Somatic mutation profile of tumor specimen 7a0266b4-b07c-41dc-8ddd-350e1b (aliquot 7a0266b4-b07c-41dc-8ddd-350e1b_D6) from CPTAC case 01CO022, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 7a0266b4-b07c-41dc-8ddd-350e1b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35bad7dc-0963-434b-9591-c0a9108eb669.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 863521b3-62a8-462c-9f1f-7fa758 (Blood Derived Normal), aliquot 863521b3-62a8-462c-9f1f-7fa758_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/876660b7-347a-407b-93e5-4fe9fdd890d3

The open-access MAF lists 3,061 somatic variants for this specimen: 2,040 protein-altering or splice-affecting, 582 silent, 439 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,361, Silent 582, Frame Shift Del 422, Intron 231, Frame Shift Ins 101, 3'UTR 83, Nonsense Mutation 73, RNA 51, 5'UTR 37, Splice Site 36, Splice Region 32, 3'Flank 20.

Variants (750 of 3,061; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 38/272 reads (14%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- ALAS2 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs863223904, CM970077; ClinVar: pathogenic; called by muse, varscan2
- ALPK3 | c.1417del p.Q473Sfs*30 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs769139957; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ASXL3 | c.6211C>T p.Q2071* | Nonsense Mutation (SNP) | VAF 58/297 reads (20%) | catalogued as rs1568369744; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.72del p.G25Dfs*186 | Frame Shift Del (DEL) | VAF 45/134 reads (34%) | catalogued as rs727502897; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/393 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C1QB | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34813378, CM072911, COSV59246036; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6074del p.G2025Afs*181 | Frame Shift Del (DEL) | VAF 29/117 reads (25%) | catalogued as rs886041417, CM071643, CM970377, COSV60392353; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.4871del p.P1624Qfs*86 | Frame Shift Del (DEL) | VAF 38/127 reads (30%) | catalogued as rs1064797082; ClinVar: pathogenic; called by mutect2, varscan2
- CTSK | c.395del p.N132Ifs*29 | Frame Shift Del (DEL) | VAF 59/208 reads (28%) | catalogued as rs1057516725; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- DMD | c.6986dup p.L2330Afs*2 | Frame Shift Ins (INS) | VAF 152/542 reads (28%) | catalogued as rs398124040; ClinVar: pathogenic; called by mutect2, varscan2
- FANCG | c.1158del p.S387Pfs*16 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs757418016; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNAI2 | c.600T>A p.F200L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs137853228; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 138/449 reads (31%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- IGHMBP2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852665, CM012773; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs147708782, CM145482; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 24/255 reads (9%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel
- STAR | c.125del p.G42Afs*67 | Frame Shift Del (DEL) | VAF 44/169 reads (26%) | catalogued as rs750549499; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TUBB4A | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs886041015, CM146503; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440del p.A2481Pfs*7 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, pindel, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, varscan2
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 23/197 reads (12%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1027318658; called by muse, mutect2, varscan2
- AADACL4 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs192329472; called by muse, mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 22/110 reads (20%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA3 | c.3876G>T p.Q1292H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1255983803; called by muse, mutect2, varscan2
- ABCA9 | c.3954dup p.G1319Rfs*2 | Frame Shift Ins (INS) | VAF 45/133 reads (34%) | catalogued as rs756170862; called by mutect2, pindel, varscan2
- ABCB10 | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as rs1469227879; called by muse, mutect2
- ABCB11 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.912); catalogued as rs946572327, COSV55596705; called by muse, mutect2, varscan2
- ABCB6 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs766607263, CM145358; called by muse, mutect2, varscan2
- ABCB8 | c.1379del p.G460Afs*31 (on ENST00000297504 / NM_001282291.2; = p.G443Afs*31 on NM_007188.5) | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | catalogued as rs1563300045; called by mutect2, pindel, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs749943218; called by mutect2, varscan2
- ABHD2 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs977424608; called by mutect2, varscan2
- ABTB1 | c.725C>T p.A242V (on ENST00000232744 / NM_172027.3; = p.A100V on NM_032548.3) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs370328576; called by muse, mutect2, varscan2
- AC126283.2 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV101144545; called by muse, mutect2, varscan2
- AC138647.1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.815); catalogued as rs1432912494; called by muse, mutect2, varscan2
- ACAN | c.5927G>T p.G1976V | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61358417, COSV61369586; called by muse, mutect2, varscan2
- ACAP3 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1483869116; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 40/170 reads (24%) | catalogued as rs748641243; called by mutect2, varscan2
- ACTA1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as COSV64203220; called by muse, mutect2, varscan2
- ACTC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV51758927, COSV51762255; called by muse, mutect2, varscan2
- ACTN2 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs143150260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV64024079; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 116/188 reads (62%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM10 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53052760; called by muse, mutect2, varscan2
- ADAM12 | c.708del p.V237Lfs*5 | Frame Shift Del (DEL) | VAF 53/257 reads (21%) | catalogued as COSV64108477; called by mutect2, pindel, varscan2
- ADAMTS12 | c.2626_2628del p.K876del | In Frame Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs767829799; called by pindel, varscan2
- ADAMTS15 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs757213675, COSV54502860; called by muse, mutect2, varscan2
- ADAMTS2 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs758470555; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADGRA1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs759071235; called by muse, mutect2, varscan2
- ADGRB1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs371439495; called by muse, mutect2, varscan2
- ADGRB2 | c.19A>T p.M7L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57077991; called by muse, mutect2, varscan2
- ADGRD1 | c.187+2T>C p.X63_splice | Splice Site (SNP) | VAF 30/108 reads (28%) | catalogued as rs756615574; called by muse, mutect2, varscan2
- ADGRG1 | c.843del p.S281Rfs*42 | Frame Shift Del (DEL) | VAF 59/233 reads (25%) | catalogued as COSV65636865; called by mutect2, pindel, varscan2
- ADH7 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as rs148046430; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | catalogued as rs761350619; called by mutect2, varscan2
- ADRA2A | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV54529135; called by muse, mutect2
- ADRA2B | c.636dup p.P213Afs*5 | Frame Shift Ins (INS) | VAF 46/168 reads (27%) | catalogued as rs756613487; called by mutect2, varscan2
- ADSL | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as rs752735865, COSV53409230; called by muse, mutect2, varscan2
- AEBP1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1473933290, COSV56261112; called by muse, varscan2
- AEBP1 | c.3040del p.Q1014Nfs*31 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | catalogued as rs767004468; called by pindel, varscan2
- AFAP1L1 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs141357304; called by muse, mutect2, varscan2
- AFDN | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); catalogued as rs947668826, COSV60055577; called by muse, mutect2, varscan2
- AGAP2 | c.608del p.G203Afs*91 | Frame Shift Del (DEL) | VAF 73/230 reads (32%) | catalogued as COSV57730384; called by mutect2, pindel, varscan2
- AGPAT5 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs138809197; called by muse, mutect2, varscan2
- AGR3 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100123961; called by muse, mutect2
- AHDC1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1287645780; called by muse, mutect2, varscan2
- AIM2 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.053); catalogued as rs770609652; called by muse, mutect2
- AJUBA | c.769dup p.A257Gfs*49 | Frame Shift Ins (INS) | VAF 38/131 reads (29%) | catalogued as rs1327169406; called by mutect2, pindel, varscan2
- AKAP8L | c.719del p.G240Afs*17 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as COSV68473580; called by mutect2, varscan2
- ALMS1 | c.7301_7302del p.E2434Vfs*7 | Frame Shift Del (DEL) | VAF 122/476 reads (26%) | catalogued as rs1246023978; called by pindel, varscan2
- AMER3 | c.585del p.R196Gfs*70 | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | catalogued as COSV58470642; called by mutect2, pindel, varscan2
- AMIGO1 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.81); catalogued as rs1257189485; called by muse, mutect2, varscan2
- ANGEL2 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs768981949; called by muse, mutect2, varscan2
- ANGPTL5 | c.813T>A p.F271L | Missense Mutation (SNP) | VAF 101/435 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs1394400156, COSV57533089; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 56/86 reads (65%) | catalogued as rs1296524808; called by mutect2, varscan2
- AP4B1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs968023503; called by muse, mutect2
- APBA2 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752622045, COSV101258138, COSV67104392; called by muse, mutect2, varscan2
- APEX1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs778301776, COSV51657557; called by muse, mutect2, varscan2
- APMAP | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV54176746; called by muse, mutect2, varscan2
- APOBEC3G | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs552054727, COSV68470300; called by muse, mutect2, varscan2
- APOL4 | c.196G>A p.V66M (on ENST00000352371 / NM_145660.2; = p.V63M on NM_030643.4) | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs763230967; called by muse, mutect2, varscan2
- AREG | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 115/426 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs762809598; called by muse, mutect2, varscan2
- ARHGAP11A | c.3044T>C p.L1015P | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770932481; called by muse, mutect2, varscan2
- ARHGAP33 | c.2492G>A p.G831E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.101); catalogued as rs760070364; called by muse, mutect2, varscan2
- ARHGAP36 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as rs140912896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP45 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1211014451; called by muse, mutect2, varscan2
- ARHGEF11 | c.4553C>T p.A1518V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs780789249; called by muse, mutect2, varscan2
- ARHGEF15 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV62726556; called by muse, mutect2, varscan2
- ARHGEF17 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs141048297; called by muse, mutect2, varscan2
- ARHGEF17 | c.4646G>A p.R1549H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475506028, COSV55235467; called by muse, mutect2, varscan2
- ARHGEF25 | c.1551_1552dup p.P518Hfs*67 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | catalogued as rs752741112; called by mutect2, varscan2
- ARHGEF40 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs770314527, COSV53884303; called by muse, mutect2, varscan2
- ARMC6 | c.740G>A p.R247H (on ENST00000392336; = p.R222H on NM_033415.4) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1339414531; called by muse, mutect2, varscan2
- ARMC7 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV99822603; called by muse, mutect2, varscan2
- ARSG | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1401470518; called by muse, mutect2
- ASB15 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs758269356, COSV51926441; called by muse, mutect2, varscan2
- ASB16 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs775918008; called by muse, mutect2, varscan2
- ASIC3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1414278953; called by muse, mutect2, varscan2
- ASPM | c.6094C>T p.R2032C | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294481719, COSV54126830; called by muse, mutect2, varscan2
- ATN1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.772); catalogued as rs1555143986; called by muse, mutect2, varscan2
- ATP10A | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs149355122; called by muse, varscan2
- ATP12A | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033107295; called by muse, mutect2, varscan2
- ATP1A1 | c.248del p.P83Lfs*58 | Frame Shift Del (DEL) | VAF 24/223 reads (11%) | catalogued as COSV55191804; called by mutect2, pindel, varscan2
- ATP2B2 | c.1309G>A p.V437M (on ENST00000352432; = p.V403M on NM_001683.5) | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276448598, COSV59493220; called by muse, mutect2, varscan2
- ATXN2L | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765799433, COSV100295000; called by muse, mutect2, varscan2
- ATXN7 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1262748939; called by muse, mutect2
- AVPR2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143480277; ClinVar: benign; called by muse, mutect2, varscan2
- AWAT2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762323805, COSV52142983, COSV52144009; called by muse, mutect2, varscan2
- AZIN2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs374073605; called by muse, mutect2, varscan2
- BAIAP3 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs753320417, COSV60985958; called by muse, mutect2
- BANP | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs756152562; called by muse, mutect2, varscan2
- BCKDHB | c.612del p.F204Lfs*26 | Frame Shift Del (DEL) | VAF 61/210 reads (29%) | catalogued as rs1210649507; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 50/205 reads (24%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND2 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs750822250, COSV66217012; called by muse, mutect2, varscan2
- BGN | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368783683, COSV59036896; called by muse, mutect2, varscan2
- BICRA | c.1993del p.Q665Sfs*59 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1414861663; called by mutect2, pindel, varscan2
- BRCA1 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58797005; called by muse, mutect2, varscan2
- BRIX1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.849); catalogued as rs555526990; called by muse, varscan2
- BUB3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | catalogued as rs1338233623; called by muse, mutect2, varscan2
- C12orf71 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs763196274, COSV70282645; called by muse, mutect2, varscan2
- C17orf97 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs202235370, COSV64076149; called by muse, mutect2, varscan2
- C1R | c.614C>A p.A205D (on ENST00000536053 / NM_001354346.2; = p.A191D on NM_001733.7) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV73293794; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 111/381 reads (29%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C1orf94 | c.1117G>A p.A373T (on ENST00000488417 / NM_001134734.2; = p.A183T on NM_032884.5) | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs781704626, COSV64913155; called by muse, mutect2, varscan2
- C3orf38 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs772231106; called by muse, mutect2, varscan2
- C6orf62 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65290459; called by muse, varscan2
- C8orf34 | c.549del p.K183Nfs*25 | Frame Shift Del (DEL) | VAF 63/175 reads (36%) | catalogued as COSV61382191; called by mutect2, pindel, varscan2
- CA12 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571042409; called by muse, mutect2, varscan2
- CACNA1D | c.5939C>T p.S1980L (on ENST00000350061 / NM_001128840.3; = p.S2000L on NM_000720.4) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.311); catalogued as rs756884300, COSV55447376; called by muse, mutect2, varscan2
- CACNA1E | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV62399431; called by muse, mutect2, varscan2
- CACNA1E | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs757105337, COSV62395307; called by muse, mutect2, varscan2
- CACNA1G | c.4009G>T p.G1337W | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733113; called by muse, mutect2, varscan2
- CACTIN | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50269665; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs201838505; called by mutect2, varscan2
- CAPN5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs868942887; called by muse, mutect2, varscan2
- CAPN7 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53777587; called by muse, mutect2, varscan2
- CAPS | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50382382; called by muse, mutect2, varscan2
- CARS2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759804272, COSV57285563; called by muse, mutect2, varscan2
- CASC3 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs528798734, COSV52868875; called by mutect2, varscan2
- CASD1 | c.1679del p.L560Cfs*30 | Frame Shift Del (DEL) | VAF 30/286 reads (10%) | catalogued as COSV51971071; called by mutect2, varscan2
- CASK | c.2317C>T p.H773Y (on ENST00000378163 / NM_001367721.1; = p.H768Y on NM_003688.3) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs398123811, COSV59367431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374168804; called by muse, mutect2, varscan2
- CBFB | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1467426352, COSV51998270; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | catalogued as rs780649799; called by mutect2, varscan2
- CCAR2 | c.2460G>T p.E820D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52383900; called by muse, mutect2, varscan2
- CCDC157 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV57839588; called by muse, mutect2
- CCDC168 | c.17467dup p.Q5823Pfs*19 | Frame Shift Ins (INS) | VAF 75/349 reads (21%) | catalogued as rs1249673334; called by mutect2, pindel, varscan2
- CCDC174 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57980264; called by muse, mutect2, varscan2
- CCDC175 | c.1895dup p.N632Kfs*6 | Frame Shift Ins (INS) | VAF 40/199 reads (20%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCDC39 | c.1045dup p.T349Nfs*2 | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | catalogued as rs747980515; called by mutect2, pindel, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC60 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1350115189, COSV59543390; called by muse, mutect2, varscan2
- CCNC | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs780791977; called by muse, varscan2
- CCNDBP1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs139518864; called by muse, mutect2, varscan2
- CD163L1 | c.2064G>T p.M688I | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV58019338; called by muse, mutect2, varscan2
- CD1A | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs770962758; called by muse, mutect2, varscan2
- CD22 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99322826; called by muse, mutect2, varscan2
- CD33 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs748041775, COSV51800414; called by muse, mutect2, varscan2
- CDA | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV66751322; called by muse, mutect2, varscan2
- CDAN1 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as rs147554753; called by muse, mutect2, varscan2
- CDC14A | c.375dup p.Y126Lfs*35 | Frame Shift Ins (INS) | VAF 33/114 reads (29%) | catalogued as rs773911500; called by mutect2, varscan2
- CDH12 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV66434135; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 19/32 reads (59%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs751765138, COSV64646935; called by muse, mutect2, varscan2
- CDH8 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.745); catalogued as rs1449609082; called by muse, mutect2, varscan2
- CDHR2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs551094108, COSV56138181; called by muse, mutect2, varscan2
- CDK5R1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); catalogued as COSV55579320; called by muse, mutect2, varscan2
- CDYL2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as rs1348845116; called by muse, mutect2, varscan2
- CEACAM8 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV54991017; called by muse, mutect2, varscan2
- CEP104 | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 117/423 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs762366585; called by muse, varscan2
- CEP295 | c.5045del p.P1682Qfs*5 | Frame Shift Del (DEL) | VAF 72/276 reads (26%) | catalogued as rs762289202; called by pindel, varscan2
- CEP350 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs770100393; called by muse, mutect2, varscan2
- CFAP46 | c.5413del p.T1805Lfs*15 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs1484029223, COSV99585845; called by mutect2, pindel, varscan2
- CFAP54 | c.8392T>C p.W2798R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs760184205; called by muse, mutect2, varscan2
- CFP | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760303151; called by muse, mutect2, varscan2
- CGRRF1 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53597589; called by muse, mutect2, varscan2
- CHADL | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.315); catalogued as rs772146480; called by muse, mutect2, varscan2
- CHAT | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1198280459; called by muse, mutect2, varscan2
- CHD5 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1333162189; called by muse, mutect2, varscan2
- CHD8 | c.7496C>A p.P2499H (on ENST00000646647 / NM_001170629.2; = p.P2220H on NM_020920.4) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1212151127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGB | c.630del p.E211Rfs*3 | Frame Shift Del (DEL) | VAF 103/325 reads (32%) | catalogued as rs1568551915; called by mutect2, pindel, varscan2
- CHRD | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs758051783; called by muse, mutect2, varscan2
- CIZ1 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs1159928822; called by muse, mutect2, varscan2
- CLCA4 | c.1953C>T p.G651= | Splice Region (SNP) | VAF 25/94 reads (27%) | catalogued as rs138241227; called by muse, mutect2, varscan2
- CLPTM1 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1026391756, COSV100493758; called by muse, mutect2, varscan2
- CLRN2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775419982, COSV71825156; called by muse, mutect2, varscan2
- CLUH | c.199del p.Q67Rfs*93 (on ENST00000435359; = p.Q105Rfs*93 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs1177334387; called by mutect2, pindel, varscan2
- CLVS1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); catalogued as rs768010044, COSV99073591; called by muse, mutect2, varscan2
- CMYA5 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV71405183; called by muse, mutect2
- CNGA4 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs761042039, COSV66005420; called by muse, mutect2, varscan2
- CNOT1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.332); catalogued as COSV57780922; called by muse, varscan2
- CNTNAP4 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1162447556; called by muse, mutect2, varscan2
- CNTNAP5 | c.708del p.R237Gfs*45 | Frame Shift Del (DEL) | VAF 51/189 reads (27%) | catalogued as COSV101443407; called by mutect2, pindel, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 72/282 reads (26%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1186482291, COSV62180334, COSV62184324; called by muse, mutect2, varscan2
- COL11A2 | c.3703del p.E1235Nfs*110 (on ENST00000341947 / NM_080680.3; = p.E1128Nfs*110 on NM_080679.2) | Frame Shift Del (DEL) | VAF 76/343 reads (22%) | catalogued as COSV59495002; called by mutect2, pindel, varscan2
- COL27A1 | c.3553C>T p.R1185W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs183678867, COSV61924456; called by muse, mutect2, varscan2
- COL27A1 | c.4384G>A p.D1462N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1481554721, COSV61930343; called by muse, mutect2, varscan2
- COL4A4 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.336); catalogued as rs199562472, COSV61629546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- COL7A1 | c.6772G>A p.A2258T | Missense Mutation (SNP) | VAF 141/434 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as rs1483117159; called by muse, mutect2, varscan2
- COMMD5 | c.16del p.A6Lfs*17 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as COSV59310992; called by mutect2, pindel, varscan2
- COMTD1 | c.247del p.D83Ifs*3 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1315373823; called by mutect2, pindel, varscan2
- COPG1 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs776776583, COSV59114331; called by muse, mutect2, varscan2
- COTL1 | c.401del p.G134Efs*48 | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | catalogued as rs1437232641; called by mutect2, pindel, varscan2
- CPED1 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs766330738, COSV60006433; called by muse, mutect2, varscan2
- CPNE9 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV56069063; called by muse, mutect2, varscan2
- CRBN | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs1183222102, COSV51641654; called by muse, mutect2, varscan2
- CROCC | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1201498304; called by muse, mutect2, varscan2
- CROCC2 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as rs747869470; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.9235C>T p.R3079C (on ENST00000520002; = p.R3078C on NM_033225.6) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs766431836, COSV59298141; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 159/558 reads (28%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTNNA1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274345685, COSV57070748, COSV57077454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs752994293; called by muse, mutect2, varscan2
- CUEDC1 | c.332del p.P111Rfs*136 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV100804649, COSV64227288; called by mutect2, pindel, varscan2
- CYB561A3 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99582611; called by muse, mutect2, varscan2
- CYP7B1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59596992; called by muse, varscan2
- DCAF15 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748698814, COSV99585975; called by muse, mutect2, varscan2
- DCHS1 | c.4895C>T p.T1632M | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762690260; called by muse, mutect2, varscan2
- DDI1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs780308662; called by muse, mutect2, varscan2
- DDN | c.1411del p.R471Efs*12 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as COSV100304819, COSV60291723; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 60/153 reads (39%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX47 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs745491237, COSV61911747; called by muse, mutect2, varscan2
- DDX60 | c.690del p.F230Lfs*4 | Frame Shift Del (DEL) | VAF 42/155 reads (27%) | catalogued as rs34458540; called by mutect2, pindel, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DENND2B | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs577617101, COSV100567187; called by muse, mutect2, varscan2
- DEPDC5 | c.2408A>G p.Y803C (on ENST00000400246; = p.Y872C on NM_014662.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs1263174457; called by muse, mutect2, varscan2
- DES | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as COSV64661015; called by muse, mutect2, varscan2
- DHCR7 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 136/408 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs373121544, CM051453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX30 | c.289G>A p.V97M (on ENST00000445061 / NM_138615.3; = p.V58M on NM_014966.3) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs765566224, COSV62395300; called by muse, mutect2, varscan2
- DHX37 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370648754; called by mutect2, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, pindel, varscan2
- DMBX1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs142474862; called by muse, mutect2, varscan2
- DMWD | c.1366del p.L456Wfs*203 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs746317972; called by mutect2, varscan2
- DNAAF3 | c.1595A>G p.N532S (on ENST00000524407 / NM_001256715.2; = p.N579S on NM_178837.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.046); catalogued as rs747488548, COSV61278745; called by muse, mutect2, varscan2
- DNAH10 | c.4579del p.T1527Rfs*4 (on ENST00000409039; = p.T1466Rfs*4 on NM_207437.3) | Frame Shift Del (DEL) | VAF 69/240 reads (29%) | catalogued as rs1223039312; called by mutect2, pindel, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 62/218 reads (28%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH9 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs1256808682, COSV52345792, COSV52356546; called by muse, mutect2, varscan2
- DNAJA1 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 55/169 reads (33%) | catalogued as rs910015688, COSV58311771; called by muse, mutect2, varscan2
- DNAJC9 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1424275371; called by muse, mutect2, varscan2
- DNER | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs765060539, COSV100518737; called by muse, mutect2, varscan2
- DNM3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62467985; called by muse, mutect2, varscan2
- DNMT3A | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs559023562, COSV53045401; called by mutect2, varscan2
- DOCK2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752159034, COSV56941164; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK8 | c.4216C>T p.R1406W | Missense Mutation (SNP) | VAF 96/501 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1226113558; called by muse, mutect2, varscan2
- DOHH | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1183468032, COSV51745363; called by muse, mutect2, varscan2
- DPP7 | c.1322dup p.A442Sfs*19 | Frame Shift Ins (INS) | VAF 26/109 reads (24%) | catalogued as rs759556695; called by mutect2, pindel, varscan2
- DPP9 | c.1330G>A p.A444T (on ENST00000598800; = p.A473T on NM_139159.5) | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs767206166; called by muse, mutect2, varscan2
- DUOXA2 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746442747; called by muse, mutect2, varscan2
- DVL1 | c.1571del p.P524Rfs*150 (on ENST00000378888 / NM_001330311.2; = p.P499Rfs*150 on NM_004421.3) | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as COSV100229386; called by mutect2, pindel, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | catalogued as rs772082432; called by mutect2, varscan2
- E2F1 | c.1303dup p.L435Pfs*39 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs1409099723; called by mutect2, pindel, varscan2
- EBF1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889503911; called by muse, varscan2
- EBF3 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs374795555; called by muse, mutect2, varscan2
- ECHDC1 | c.802_805del p.C268Qfs*18 (on ENST00000531967 / NM_001139510.1; = p.C262Qfs*18 on NM_001002030.2) | Frame Shift Del (DEL) | VAF 54/297 reads (18%) | catalogued as rs778587969; called by pindel, varscan2
- EDIL3 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs747133333; called by muse, mutect2, varscan2
- EFHC1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs374661645; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- EGR1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); catalogued as COSV53518249; called by muse, mutect2, varscan2
- EIF4A2 | c.78C>T p.S26= | Splice Region (SNP) | VAF 65/258 reads (25%) | catalogued as rs371691662, COSV100125381; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs755832199, COSV57518463; called by muse, mutect2, varscan2
- ELMOD3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs371254266; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 52/176 reads (30%) | catalogued as rs766700925; called by mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs759858342; called by mutect2, varscan2
- EML6 | c.3456del p.F1152Lfs*10 | Frame Shift Del (DEL) | VAF 83/258 reads (32%) | catalogued as rs745447718; called by mutect2, varscan2
- ENO3 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs1481270593; called by muse, mutect2, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- ENTPD4 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs748019875; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHA5 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.121); catalogued as rs770802873, COSV56639233; called by muse, mutect2, varscan2
- EPHA7 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs769773179; called by muse, mutect2, varscan2
- EPHB4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs904491005; called by mutect2, varscan2
- EPX | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as COSV56599455; called by muse, mutect2, varscan2
- ERICH2 | c.261del p.K87Nfs*5 | Frame Shift Del (DEL) | VAF 50/173 reads (29%) | catalogued as rs765922748; called by mutect2, pindel, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | catalogued as rs779855268; called by mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- ESPNL | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs753772292; called by muse, mutect2, varscan2
- ESR2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs142737037; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs775950025; called by mutect2, varscan2
- ETS2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100711355; called by muse, mutect2, varscan2
- EXOC4 | c.2614A>G p.R872G | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54103546; called by muse, mutect2, varscan2
- EXT1 | c.1841A>G p.N614S | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as CD130838; called by muse, mutect2, varscan2
- EXTL3 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1405303377; called by muse, mutect2, varscan2
- F8 | c.2348del p.N783Mfs*3 | Frame Shift Del (DEL) | VAF 47/176 reads (27%) | catalogued as CD103782, CD123961; called by mutect2, pindel, varscan2
- FAM102A | c.886C>T p.R296W (on ENST00000373095 / NM_001035254.3; = p.R154W on NM_203305.2) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1001513189; called by muse, mutect2, varscan2
- FAM155B | c.378del p.A127Pfs*98 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | catalogued as rs1569256905, COSV52935612; called by mutect2, pindel, varscan2
- FAM193B | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs760949586; called by muse, mutect2, varscan2
- FAM205A | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.245); catalogued as rs527347713, COSV66488681; called by muse, varscan2
- FAM20C | c.901del p.Y301Ifs*36 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | catalogued as rs1261053639; called by mutect2, varscan2
- FAM214A | c.2042dup p.N681Kfs*2 | Frame Shift Ins (INS) | VAF 57/258 reads (22%) | catalogued as rs762546731; called by mutect2, varscan2
- FAM3C | c.594+2T>G p.X198_splice | Splice Site (SNP) | VAF 44/144 reads (31%) | catalogued as COSV63435521; called by muse, mutect2, varscan2
- FAM47A | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs878906003; called by muse, mutect2, varscan2
- FAM53A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs1381254949; called by muse, mutect2, varscan2
- FAM9B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.75); catalogued as COSV59119225; called by muse, mutect2, varscan2
- FASN | c.7030G>A p.V2344I | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as rs766955776; called by muse, mutect2, varscan2
- FASN | c.1236del p.A413Hfs*39 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | catalogued as COSV60760319; called by mutect2, varscan2
- FAT1 | c.5086T>C p.S1696P | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs1246076935; called by muse, mutect2, varscan2
- FAT3 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746609537, COSV53088460; called by muse, mutect2, varscan2
- FAT3 | c.12710A>G p.Y4237C | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99971181; called by muse, mutect2, varscan2
- FAT4 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755643759, COSV67882388; called by muse, mutect2, varscan2
- FAT4 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs200898075, COSV58670988; called by muse, mutect2, varscan2
- FBN2 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs138046782, COSV52493545; called by muse, mutect2, varscan2
- FBP1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941328; called by muse, mutect2, varscan2
- FBXL6 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs201941787; called by muse, mutect2, varscan2
- FCGBP | c.6655G>A p.A2219T | Missense Mutation (SNP) | VAF 84/458 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as COSV99664632; called by mutect2, varscan2
- FDPS | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV52739401; called by muse, mutect2, varscan2
- FERD3L | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762163, COSV51764328; called by muse, varscan2
- FEZ2 | c.854del p.N285Mfs*19 | Frame Shift Del (DEL) | VAF 127/462 reads (27%) | catalogued as rs772264399; called by mutect2, pindel, varscan2
- FEZF2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs1330229915; called by muse, mutect2, varscan2
- FGD5 | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328852195; called by muse, mutect2, varscan2
- FGL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs569344238, COSV50380826; called by muse, mutect2, varscan2
- FLNC | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.212); catalogued as rs1386986739, CM1512362, COSV57963859; called by muse, mutect2, varscan2
- FLT1 | c.2266A>G p.N756D | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs370222607; called by muse, varscan2
- FLT4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs368167894; called by muse, mutect2, varscan2
- FOCAD | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs559717390; called by muse, mutect2, varscan2
- FOXA1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51650573, COSV99163750; called by muse, mutect2, varscan2
- FOXD4L1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 136/712 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52073936; called by muse, varscan2
- FRMD6 | c.1526C>A p.S509* (on ENST00000344768 / NM_001267046.2; = p.S501* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 49/178 reads (28%) | catalogued as COSV100655772; called by muse, mutect2, varscan2
- FRRS1L | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101643920; called by muse, varscan2
- FSIP2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs911042698, COSV58081742; called by muse, mutect2, varscan2
- FUBP1 | c.1926+1G>T p.X642_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV53928267; called by muse, mutect2, varscan2
- GAD2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747241251, COSV52154382; called by muse, mutect2, varscan2
- GALNT10 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777623511; called by muse, mutect2, varscan2
- GALNT16 | c.956del p.G319Efs*83 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs763094427; called by mutect2, pindel, varscan2
- GARNL3 | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs758873701, COSV59223670; called by muse, mutect2, varscan2
- GAS1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV100075735; called by muse, mutect2, varscan2
- GAS2L1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs568890997, COSV99329442; called by muse, mutect2, varscan2
- GCN1 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs779688682, COSV56114652; called by muse, mutect2, varscan2
- GCNA | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs760680011; called by muse, mutect2, varscan2
- GDAP2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763963913, COSV65612787; called by muse, mutect2, varscan2
- GFY | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1568632479; called by muse, mutect2, varscan2
- GGN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV53057040; called by muse, varscan2
- GJB4 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs199688130, COSV99044994; called by muse, mutect2, varscan2
- GJD4 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs773395724, COSV58701924; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI1 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs368078339; called by muse, mutect2, varscan2
- GLI2 | c.1766G>A p.R589H (on ENST00000361492 / NM_001374353.1; = p.R606H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs745409561, COSV58038657, COSV58048899; called by muse, mutect2, varscan2
- GLP2R | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs146116783; called by muse, mutect2, varscan2
- GLT1D1 | c.290del p.N97Tfs*21 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | catalogued as rs769605828, COSV55878296; called by mutect2, pindel, varscan2
- GMEB1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as rs772052369; called by muse, mutect2, varscan2
- GNAZ | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs369848697, COSV99321215; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs370172185; called by muse, mutect2, varscan2
- GOLGA8M | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1250158456; called by muse, mutect2, varscan2
- GP2 | c.584G>A p.R195H (on ENST00000381362 / NM_001007240.3; = p.R192H on NM_001502.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as rs575924699, COSV56892408; called by muse, mutect2, varscan2
- GPATCH2 | c.634del p.R212Efs*3 | Frame Shift Del (DEL) | VAF 42/184 reads (23%) | catalogued as rs945102298; called by mutect2, pindel, varscan2
- GPR152 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.11); catalogued as rs1420343622; called by muse, mutect2, varscan2
- GPR161 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as rs961642617, COSV54788550; called by muse, mutect2, varscan2
- GPR176 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54448022; called by muse, mutect2, varscan2
- GPR88 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs747404171; called by muse, varscan2
- GPRC5D | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57432247; called by muse, mutect2, varscan2
- GRB7 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs149195822; called by muse, mutect2, varscan2
- GRIK3 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs746478247, COSV66135600, COSV66143041; called by muse, mutect2, varscan2
- GRIN2B | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.523); catalogued as rs756224637, COSV74208030; called by muse, mutect2, varscan2
- GRIN3B | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs1362248341; called by muse, mutect2
- GRIN3B | c.1020G>A p.R340= | Splice Region (SNP) | VAF 26/54 reads (48%) | catalogued as rs1178087803; called by muse, mutect2, varscan2
- GRIP2 | c.3134C>T p.P1045L (on ENST00000619221; = p.P948L on NM_001080423.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); catalogued as COSV56124192; called by muse, mutect2, varscan2
- GRK4 | c.259G>A p.V87M (on ENST00000398052 / NM_182982.3; = p.V55M on NM_005307.3) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs990679341; called by muse, mutect2, varscan2
- GRM3 | c.579del p.D194Tfs*23 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | catalogued as rs1470079689; called by mutect2, pindel, varscan2
- GRM4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); catalogued as COSV65214100; called by muse, mutect2
- GRM5 | c.2899G>A p.A967T (on ENST00000305447 / NM_001143831.2; = p.A935T on NM_000842.4) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as rs901648577; called by muse, mutect2, varscan2
- GSDMA | c.1150del p.L384Cfs*14 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | catalogued as COSV52856978; called by mutect2, pindel, varscan2
- GSN | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 107/338 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as rs371328761; called by muse, mutect2, varscan2
- GTPBP2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs1342986397, COSV61077214; called by muse, mutect2, varscan2
- GUCA1A | c.204C>T p.D68= | Splice Region (SNP) | VAF 64/227 reads (28%) | catalogued as rs776251040, COSV50003850; called by muse, mutect2, varscan2
- GYPC | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs769463770; called by muse, mutect2, varscan2
- H1-7 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs746583140, COSV58601617; called by muse, mutect2, varscan2
- H2AC4 | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1411183486; called by muse, mutect2, varscan2
- H3-4 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.564); catalogued as rs373549345; called by muse, mutect2, varscan2
- HAGHL | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs990716473; called by muse, mutect2, varscan2
- HCAR2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as rs140267406; called by muse, mutect2, varscan2
- HCN1 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1232040161; called by muse, mutect2, varscan2
- HCN1 | c.1534del p.M512Cfs*19 | Frame Shift Del (DEL) | VAF 181/602 reads (30%) | catalogued as rs772669067; called by mutect2, varscan2
- HDAC6 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs868973122; called by muse, mutect2
- HDC | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as rs899820647; called by muse, mutect2
- HDDC2 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs368930540; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HECW2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs143599492; called by muse, mutect2, varscan2
- HERC1 | c.5634del p.V1879Lfs*26 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | catalogued as rs1287865515; called by mutect2, varscan2
- HERC1 | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as rs764310338; called by muse, mutect2, varscan2
- HEY2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64239750; called by muse, mutect2, varscan2
- HIP1 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs200972887; called by muse, mutect2, varscan2
- HIP1R | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142435037; called by muse, varscan2
- HIPK1 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); catalogued as rs780735126; called by muse, varscan2
- HIPK2 | c.2688G>C p.E896D | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61225630; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 59/157 reads (38%) | catalogued as rs761272507; called by mutect2, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as COSV57466638; called by pindel, varscan2
- HNRNPH2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs782704910, COSV54508591; called by muse, mutect2, varscan2
- HOXA2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs991740115, COSV56066217; called by muse, mutect2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs761197780; called by mutect2, varscan2
- HOXD10 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV50895107; called by muse, mutect2, varscan2
- HR | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773970960; called by muse, mutect2, varscan2
- HSPB3 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100115915; called by muse, mutect2, varscan2
- HSPG2 | c.5801G>A p.R1934Q | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs756689841, COSV65976960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ID4 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746070477; called by muse, mutect2, varscan2
- IFRD2 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178351375; called by muse, mutect2, varscan2
- IFT140 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs1307461796, COSV68496769; called by muse, mutect2, varscan2
- IMMP1L | c.432+2T>A p.X144_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | catalogued as COSV99541017; called by muse, mutect2, varscan2
- INHBA | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54223147; called by muse, mutect2, varscan2
- INPP5F | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 26/109 reads (24%) | catalogued as rs755932183, COSV62821589; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs779930616; called by mutect2, pindel, varscan2
- INTS7 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65343913; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 23/140 reads (16%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPP | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV63432620; called by muse, mutect2, varscan2
- IQGAP3 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs542327665; called by muse, mutect2, varscan2
- IRF2BPL | c.818del p.P273Hfs*72 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs1331422798; called by mutect2, pindel, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs769008935, COSV57359884; called by muse, mutect2, varscan2
- IRX4 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144026313; called by muse, mutect2, varscan2
- IST1 | c.767C>T p.T256M (on ENST00000535424 / NM_001270976.1; = p.T243M on NM_014761.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs150623968; called by muse, mutect2, varscan2
- ITGAD | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs534769337; called by muse, mutect2, varscan2
- ITGAL | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63321176; called by muse, mutect2, varscan2
- ITIH2 | c.741G>A p.A247= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as rs769730496, COSV64432783, COSV64434540; called by muse, mutect2, varscan2
- ITPK1 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV50895502; called by muse, mutect2
- ITPR2 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67264302; called by muse, mutect2, varscan2
- ITPR3 | c.4747G>A p.A1583T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1412127724, COSV65410901; called by muse, mutect2, varscan2
- JAK2 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs370705658; called by muse, mutect2, varscan2
- JAKMIP1 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs765708383, COSV51532503; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 154/320 reads (48%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- KAT5 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57730150; called by muse, mutect2, varscan2
- KBTBD13 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs762769253; called by muse, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 68/230 reads (30%) | catalogued as rs774820321; called by mutect2, varscan2
- KBTBD7 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as COSV65266875; called by muse, mutect2, varscan2
- KCND1 | c.691T>C p.F231L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54413598; called by muse, mutect2, varscan2
- KCNJ13 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as COSV99289294; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as rs766469179, COSV56415804; called by mutect2, varscan2
- KCNQ1 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511173, CM990764; called by muse, mutect2, varscan2
- KCTD19 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757641572; called by muse, mutect2, varscan2
- KDM4D | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 56/195 reads (29%) | catalogued as rs895780588, COSV58633807; called by muse, mutect2, varscan2
- KDM5C | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs781969097; called by muse, mutect2, varscan2
- KIAA0100 | c.4111C>T p.R1371W | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387008111, COSV66494486; called by muse, mutect2, varscan2
- KIAA1549 | c.4896del p.G1633Afs*78 | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | catalogued as COSV54314060; called by mutect2, pindel, varscan2
- KIAA1671 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs898134105; called by muse, mutect2, varscan2
- KIAA1671 | c.4762T>C p.Y1588H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs940128996; called by muse, mutect2
- KIAA1755 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99642200; called by muse, mutect2, varscan2
- KIF20A | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs564342284, COSV67510116; called by muse, mutect2, varscan2
- KIF24 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 31/115 reads (27%) | catalogued as rs775329733, COSV61453477, COSV61456721; called by muse, mutect2, varscan2
- KIR2DL4 | c.1175T>G p.M392R (on ENST00000396284; = p.M318R on NM_001080770.2) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1467300011; called by muse, mutect2, varscan2
- KIRREL3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370309110; called by muse, mutect2, varscan2
- KL | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104430435; called by muse, mutect2, varscan2
- KLHDC7A | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV68769541; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 47/175 reads (27%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL30 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs375859214; called by muse, mutect2, varscan2
- KLHL32 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1002538688, COSV65110305; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs762518653; called by mutect2, pindel, varscan2
- KLHL4 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs1387738089; called by muse, mutect2, varscan2
- KMT5B | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs146086325; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KNTC1 | c.3443del p.L1148Yfs*2 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs1444088158; called by pindel, varscan2
- KRT79 | c.762T>C p.D254= | Splice Region (SNP) | VAF 33/100 reads (33%) | catalogued as COSV57938247; called by muse, mutect2, varscan2
- KRTAP2-4 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1465369130; called by muse, mutect2, varscan2
- KRTAP4-1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as rs753454106, COSV100893536; called by muse, mutect2, varscan2
- KSR2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as rs1243541251; called by muse, mutect2, varscan2
- L3MBTL4 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1019580644; called by muse, mutect2, varscan2
- LACTBL1 | c.583G>A p.A195T (on ENST00000618559; = p.A240T on NM_001289974.2) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs867522654, COSV70777202; called by muse, mutect2, varscan2
- LAMA1 | c.8290G>A p.A2764T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs781696472, COSV101057971; called by muse, mutect2, varscan2
- LAMA2 | c.8625dup p.A2876Sfs*30 | Frame Shift Ins (INS) | VAF 120/421 reads (29%) | catalogued as rs749162150; called by mutect2, pindel, varscan2
- LAMA5 | c.9184G>A p.A3062T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs747816275, COSV53358063; called by muse, mutect2, varscan2
- LAMB1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753663712; called by muse, mutect2, varscan2
- LAMB4 | c.26dup p.L9Ffs*14 | Frame Shift Ins (INS) | VAF 48/252 reads (19%) | catalogued as rs747409331; called by mutect2, varscan2
- LAMP1 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs200783496; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDLR | c.1358+6C>T | Splice Region (SNP) | VAF 82/310 reads (26%) | catalogued as rs763813169, COSV99369531; called by muse, mutect2, varscan2
- LDLRAD4 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63339457; called by muse, mutect2, varscan2
- LHFPL6 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs373058215; called by muse, mutect2, varscan2
- LILRA4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs756747611, COSV99393511; called by muse, mutect2, varscan2
- LMNTD1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs745367335; called by muse, mutect2, varscan2
- LMNTD1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753009168, COSV51450952; called by mutect2, varscan2
- LOX | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); catalogued as COSV50240169; called by muse, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | catalogued as rs746133895; called by mutect2, varscan2
- LPIN1 | c.1101del p.S368Lfs*4 | Frame Shift Del (DEL) | VAF 66/219 reads (30%) | catalogued as rs745547203; called by mutect2, varscan2
- LRATD2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs374699943; called by mutect2, varscan2
- LRFN2 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57823665; called by mutect2, varscan2
- LRFN2 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599347; called by muse, mutect2, varscan2
- LRPAP1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs376919981; called by mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC38 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 126/440 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs762171811; called by muse, mutect2, varscan2
- LRRC61 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777325652; called by muse, mutect2, varscan2
- LRRC70 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.715); catalogued as rs1561371808; called by muse, mutect2, varscan2
- LRRC8C | c.1524dup p.W509Lfs*20 | Frame Shift Ins (INS) | VAF 48/196 reads (24%) | catalogued as rs762972819; called by mutect2, varscan2
- LRRK1 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as rs1415786642; called by muse, mutect2, varscan2
- LRSAM1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs777784051, COSV100031284; called by muse, mutect2, varscan2
- LRWD1 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs767161528, COSV52999977; called by muse, mutect2, varscan2
- LTBP4 | c.454C>A p.L152M (on ENST00000308370 / NM_001042544.1; = p.L115M on NM_003573.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1439390570; called by muse, mutect2, varscan2
- LYVE1 | c.594del p.K198Nfs*2 | Frame Shift Del (DEL) | VAF 64/254 reads (25%) | catalogued as rs1241350290; called by mutect2, pindel, varscan2
- LZTR1 | c.1859T>C p.L620P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53151959; called by muse, mutect2
- MAGI1 | c.2558G>A p.R853H (on ENST00000402939 / NM_001033057.2; = p.R881H on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375197593, COSV58337552; called by muse, mutect2, varscan2
- MAMDC2 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as rs754879235; called by muse, mutect2, varscan2
- MAN1C1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760511398, COSV99848098; called by muse, mutect2, varscan2
- MAP2 | c.2192T>C p.I731T | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52280745; called by muse, mutect2
- MAP3K6 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs773086020; called by muse, mutect2, varscan2
- MAP4K1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs752137254; called by mutect2, varscan2
- MAPT | c.1514C>T p.A505V (on ENST00000262410 / NM_001377265.1; = p.A430V on NM_016835.4) | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99289868; called by muse, mutect2
- MBL2 | c.218del p.P73Lfs*68 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | catalogued as rs747467008; called by mutect2, pindel, varscan2
- MBNL1 | c.846G>T p.E282D | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV99220079; called by muse, mutect2
- MBOAT7 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201813053; called by muse, mutect2, varscan2
- MCAM | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs756862205; called by muse, mutect2, varscan2
- MCF2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777439449; called by muse, mutect2, varscan2
- MCHR1 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV50760429; called by mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 47/152 reads (31%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDGA2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs748391283, COSV67811984; called by muse, mutect2, varscan2
- MDN1 | c.1323dup p.A442Cfs*34 | Frame Shift Ins (INS) | VAF 33/109 reads (30%) | catalogued as rs1387576931; called by mutect2, pindel, varscan2
- MECP2 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 59/192 reads (31%) | catalogued as CM057720; called by muse, mutect2, varscan2
- MED12 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1474736821, COSV61347292; called by muse, mutect2, varscan2
- MED16 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs761731274; called by muse, mutect2, varscan2
- MED27 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs992385394; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 61/95 reads (64%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs769987847; called by mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 62/476 reads (13%) | catalogued as rs746398787; called by mutect2, varscan2
- MGAT4C | c.1025del p.P342Lfs*8 | Frame Shift Del (DEL) | VAF 111/404 reads (27%) | catalogued as rs772624713; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 62/106 reads (58%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1037333676; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 130/502 reads (26%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MMS22L | c.2819A>G p.Q940R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs368530769; called by muse, mutect2, varscan2
- MON1A | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616606; called by muse, mutect2
- MON2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs762118035; called by muse, mutect2, varscan2
- MRI1 | c.898C>T p.R300* (on ENST00000040663 / NM_001031727.4; = p.R253* on NM_032285.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/189 reads (25%) | catalogued as rs1192763361, COSV50005496; called by muse, mutect2, varscan2
- MROH2A | c.4967_4968del p.T1656Sfs*4 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1439240788; called by pindel, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs1558718327, COSV62567684; called by mutect2, pindel, varscan2
- MRPS22 | c.984+15del | Splice Region (DEL) | VAF 82/318 reads (26%) | catalogued as rs372892045; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- MRPS33 | c.320A>G p.*107Wext*34 | Nonstop Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs1473856743; called by muse, mutect2, varscan2
- MSANTD3-TMEFF1 | c.38dup p.E14Gfs*21 | Frame Shift Ins (INS) | VAF 38/148 reads (26%) | catalogued as rs756460439; called by mutect2, pindel, varscan2
- MSTO1 | c.1268G>T p.R423I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55471905; called by muse, mutect2
- MSX1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs760914206, COSV101235792; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 68/207 reads (33%) | catalogued as rs759847587; called by mutect2, varscan2
- MTG1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as rs1329853305; called by muse, mutect2, varscan2
- MTOR | c.3394C>T p.R1132* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV63873167; called by muse, varscan2
- MTOR | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100816434; called by muse, mutect2, varscan2
- MTPAP | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 111/377 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs138262385; called by muse, mutect2, varscan2
- MUC16 | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV67451843; called by muse, mutect2, varscan2
- MXRA5 | c.5878G>A p.V1960I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV54234921; called by muse, mutect2, varscan2
- MYLK | c.2692C>T p.R898* | Nonsense Mutation (SNP) | VAF 23/370 reads (6%) | catalogued as rs747171137, COSV100658830; called by muse, mutect2
- MYLK3 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs779807650, COSV67366332; called by muse, mutect2, varscan2
- MYNN | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as rs113291870; called by muse, mutect2, varscan2
- MYO10 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.307); catalogued as rs539711647, COSV57016749; called by muse, mutect2, varscan2
- MYO15A | c.2199del p.D734Tfs*3 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs1555539272; called by mutect2, pindel, varscan2
- MYO18A | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs780351991, COSV62866958; called by muse, mutect2, varscan2
- MYO18A | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755153578, COSV62863445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYRF | c.363del p.I122Sfs*31 (on ENST00000278836 / NM_001127392.3; = p.I113Sfs*31 on NM_013279.4) | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as COSV53894504; called by mutect2, pindel, varscan2
- MZT2A | c.208del p.L70Sfs*16 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs770250515; called by mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAALADL1 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs201556646; called by muse, mutect2, varscan2
- NAV1 | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs764886031, COSV55217986; called by muse, varscan2
- NAV1 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374751019; called by muse, mutect2, varscan2
- NAV2 | c.1981G>T p.V661F (on ENST00000396087 / NM_001244963.2; = p.V638F on NM_145117.5) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.423); catalogued as COSV62316295; called by muse, mutect2, varscan2
- NBEAL1 | c.6998dup p.N2333Kfs*13 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | catalogued as rs1309479121; called by mutect2, pindel, varscan2
- NCDN | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1012827506, COSV61934540; called by muse, mutect2, varscan2
- NCOA2 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs1221412688; called by muse, mutect2, varscan2
- NDUFA4 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1286100412, COSV60011788; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as rs747914168; called by mutect2, varscan2
- NEDD4 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59065621; called by muse, mutect2, varscan2
- NELFA | c.454T>C p.C152R (on ENST00000542778; = p.C141R on NM_005663.5) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100424864; called by muse, mutect2, varscan2
- NEURL2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773767068, COSV51942890; called by muse, mutect2, varscan2
- NF1 | c.6316G>A p.V2106I (on ENST00000358273 / NM_001042492.3; = p.V2085I on NM_000267.3) | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs755791578, COSV62211755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101044704; called by muse, mutect2, varscan2
- NIN | c.6008A>G p.Q2003R (on ENST00000382041 / NM_182946.1; = p.Q1290R on NM_016350.4) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55404080; called by muse, mutect2
- NISCH | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202168458; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 86/328 reads (26%) | catalogued as rs763440516; called by mutect2, varscan2
- NLGN1 | c.2296A>G p.M766V | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs372166495; called by muse, mutect2, varscan2
- NLRP5 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs775094722, COSV101173489; called by muse, mutect2, varscan2
- NLRP7 | c.2341T>C p.F781L (on ENST00000340844 / NM_206828.3; = p.F753L on NM_139176.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766955200; called by muse, mutect2, varscan2
- NMI | c.338_340del p.E113del | In Frame Del (DEL) | VAF 58/242 reads (24%) | catalogued as rs1428544634; called by pindel, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs1402340327; called by mutect2, pindel, varscan2
- NOS1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57612231; called by muse, mutect2, varscan2
- NPDC1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs780477037, COSV58665303; called by muse, mutect2, varscan2
- NPHS1 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 93/301 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs768047120; called by muse, mutect2
- NPTXR | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745582200, COSV60728219; called by muse, mutect2, varscan2
- NPY2R | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs1302442725; called by muse, mutect2, varscan2
- NR1H2 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs777860912; called by mutect2, varscan2
- NRXN3 | c.1744G>A p.A582T (on ENST00000557594 / NM_001272020.2; = p.A1006T on NM_004796.6) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55333949; called by muse, mutect2, varscan2
- NSMAF | c.2446+8T>C | Splice Region (SNP) | VAF 28/118 reads (24%) | catalogued as rs373519664; called by muse, mutect2, varscan2
- NT5C1B | c.674G>A p.R225H (on ENST00000359846 / NM_001199086.2; = p.R165H on NM_033253.4) | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs563389452, COSV100410056; called by muse, varscan2
- NTRK3 | c.2286G>T p.E762D (on ENST00000360948 / NM_001012338.2; = p.E748D on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1361372348, COSV62305415; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP210 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs750633056, COSV104392230; called by muse, mutect2, varscan2
- NUP88 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56707322; called by muse, mutect2, varscan2
- NWD1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs575435644; called by muse, varscan2
- NXF5 | n.1443-1G>T | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99534603; called by muse, mutect2, varscan2
- OAS3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 125/468 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs751686088; called by muse, mutect2, varscan2
- OBSCN | c.3869C>T p.T1290M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs373940171; called by muse, mutect2
- OBSCN | c.8961C>A p.C2987* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as rs570299277, COSV99470554; called by muse, mutect2
- OBSCN | c.16237G>A p.V5413M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750411783, COSV99482086; called by muse, mutect2, varscan2
- OBSL1 | c.5017C>T p.R1673W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376646991; called by muse, varscan2
- OBSL1 | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs771230527; called by muse, mutect2, varscan2
- OGFR | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs772448691, COSV99283861; called by muse, mutect2, varscan2
- OLFM2 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs868535638, COSV53430543; called by muse, mutect2, varscan2
- OLFM2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs535936235, COSV99322083; called by muse, mutect2, varscan2
- OMA1 | c.697T>G p.F233V | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs377321455; called by muse, mutect2, varscan2
- OPHN1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs984868981; called by muse, mutect2, varscan2
- OR11H1 | c.206A>T p.N69I | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99422056; called by muse, varscan2
- OR1A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs775031743; called by muse, mutect2, varscan2
- OR1J1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as rs762965619, COSV52237360, COSV52239396; called by muse, mutect2, varscan2
- OR1L6 | c.851C>T p.A284V (on ENST00000373684; = p.A248V on NM_001004453.2) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772211538; called by muse, mutect2, varscan2
- OR2C3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs562326145, COSV63574257, COSV63574402, COSV63574958; called by muse, varscan2
- OR2T11 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100424987; called by muse, mutect2, varscan2
- OR4K5 | c.505del p.C169Vfs*5 | Frame Shift Del (DEL) | VAF 48/454 reads (11%) | catalogued as rs755690620; called by mutect2, pindel, varscan2
- OR4M1 | c.258del p.F86Lfs*6 | Frame Shift Del (DEL) | VAF 50/372 reads (13%) | catalogued as COSV60064043; called by mutect2, pindel, varscan2
- OR51A4 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs573932130; called by muse, mutect2, varscan2
- OR5AK2 | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377265659; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 62/184 reads (34%) | catalogued as rs747074822; called by mutect2, varscan2
- OR7G2 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV59688999; called by muse, mutect2
- OR8I2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs141804427; called by muse, mutect2, varscan2
- OR8K5 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.938); catalogued as rs372949225, COSV100537202; called by muse, mutect2
- OR8U1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs771754031, COSV56415298; called by muse, varscan2
- OSBPL8 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 58/224 reads (26%) | catalogued as rs1203486900; called by muse, mutect2, varscan2
- OSGEPL1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99918260; called by muse, mutect2, varscan2
- OTOGL | c.4163G>A p.S1388N (on ENST00000547103; = p.S1379N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV72006466; called by muse, mutect2, varscan2
- OTX1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV56993804; called by muse, mutect2, varscan2
- P3H2 | c.1289dup p.L431Afs*18 | Frame Shift Ins (INS) | VAF 38/159 reads (24%) | catalogued as rs1560347618; called by mutect2, pindel, varscan2
- PACSIN3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs779623305, COSV54066320; called by muse, varscan2
- PAN3 | c.2579T>C p.V860A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV99145360; called by muse, mutect2, varscan2
- PAPPA | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375396659; called by muse, mutect2, varscan2
- PAPPA2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755342431, COSV62774296, COSV62782315; called by muse, mutect2, varscan2
- PAQR3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs532816752; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PARD3B | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs199890873, COSV62507799; called by muse, mutect2, varscan2
- PARD3B | c.3049C>T p.R1017C (on ENST00000406610 / NM_001302769.2; = p.R948C on NM_057177.7) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs554253375; called by muse, mutect2, varscan2
- PAX1 | c.501del p.S168Afs*47 | Frame Shift Del (DEL) | VAF 83/336 reads (25%) | catalogued as COSV68273123; called by mutect2, pindel, varscan2
- PCBP4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1008073492; called by muse, mutect2, varscan2
- PCDH10 | c.360del p.S121Lfs*7 | Frame Shift Del (DEL) | VAF 55/238 reads (23%) | catalogued as rs759095467; called by mutect2, pindel, varscan2
- PCDH19 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 140/460 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867012022, COSV55259918; called by muse, mutect2, varscan2
- PCDH8 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100132091; called by muse, varscan2
- PCDHA12 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56479342; called by muse, mutect2, varscan2
- PCDHA7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 118/414 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65344678; called by muse, varscan2
- PCDHB5 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs782058253; called by muse, mutect2, varscan2
- PCDHB9 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs782490536, COSV53377046; called by muse, mutect2, varscan2
- PCGF6 | c.648_651del p.R217Vfs*2 | Frame Shift Del (DEL) | VAF 36/182 reads (20%) | catalogued as rs1205112145; called by pindel, varscan2
- PCNA | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs746900735; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 72/232 reads (31%) | catalogued as rs747131399; called by mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 64/94 reads (68%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZD2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1029396347, COSV56853334; called by muse, mutect2, varscan2
- PDZD2 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs561926039; called by muse, mutect2, varscan2
- PER3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs114300822; called by muse, mutect2, varscan2
- PGRMC1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs770618912; called by muse, mutect2
- PHB2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 50/166 reads (30%) | catalogued as rs1555151101; called by muse, mutect2, varscan2
- PHF20L1 | c.2250del p.M750Ifs*19 | Frame Shift Del (DEL) | VAF 24/245 reads (10%) | catalogued as COSV55189345; called by mutect2, pindel, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs761575760; called by mutect2, varscan2
- PHKA2 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs755462710; called by muse, mutect2, varscan2
- PHTF2 | c.879A>G p.I293M (on ENST00000248550 / NM_001366089.1; = p.I255M on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs780362374; called by muse, mutect2, varscan2
- PI4KA | c.5431C>T p.R1811* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as rs1239957253, COSV55422586; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 68/297 reads (23%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 54/152 reads (36%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PIK3C2A | c.3697A>G p.I1233V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1186223590; called by muse, mutect2
- PKD1 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as rs752035888, COSV99239371; called by muse, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 62/226 reads (27%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 69/289 reads (24%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLEKHA8 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs950425344, COSV99321287; called by muse, mutect2, varscan2
- PLEKHG5 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV61705925; called by muse, mutect2, varscan2
- PLXNA3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.496); catalogued as rs868987554; called by muse, mutect2, varscan2
- PLXNA4 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58126470; called by muse, mutect2, varscan2
- PLXNB1 | c.4759C>T p.R1587W | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004255185, COSV56488379; called by muse, mutect2, varscan2
- PNMA3 | c.261dup p.P88Afs*10 | Frame Shift Ins (INS) | VAF 23/112 reads (21%) | catalogued as rs781795278; called by mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 50/79 reads (63%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs751563432, COSV53560496; called by muse, mutect2, varscan2
- POLR1A | c.5116G>A p.V1706I | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as rs751227263; called by muse, mutect2, varscan2
- POM121 | c.1823del p.P608Rfs*57 (on ENST00000434423; = p.P343Rfs*57 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV99987426; called by mutect2, pindel, varscan2
- POM121L12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs749141757, COSV68692580, COSV68693810; called by muse, mutect2, varscan2
- POU4F1 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65883997; called by muse, mutect2, varscan2
- PPARGC1B | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs1402894502; called by muse, mutect2, varscan2
- PPFIA4 | c.1801G>A p.A601T (on ENST00000447715; = p.A602T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55314984; called by muse, mutect2, varscan2
- PPL | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1278065459, COSV62051172; called by muse, mutect2, varscan2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPM1J | c.237del p.L80Cfs*102 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs1553190966; called by mutect2, varscan2
- PPOX | c.342del p.X114_splice | Splice Site (DEL) | VAF 49/178 reads (28%) | catalogued as CS0911074; called by mutect2, pindel, varscan2
- PPP1R12A | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs757625740; called by muse, mutect2, varscan2
- PPP1R16A | c.685dup p.L229Pfs*33 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | catalogued as rs1315376411; called by mutect2, pindel, varscan2
- PPP1R2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs751525820, COSV60497702; called by muse, mutect2, varscan2
- PPP1R3A | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 130/378 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs139926471; called by muse, mutect2, varscan2
- PPP1R7 | c.673A>T p.N225Y | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99297684; called by muse, mutect2, varscan2
- PRAG1 | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV58165628; called by muse, mutect2, varscan2
- PRAMEF11 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs748086924; called by muse, mutect2, varscan2
- PRAMEF4 | c.1226del p.N409Tfs*32 | Frame Shift Del (DEL) | VAF 68/370 reads (18%) | catalogued as COSV52439197; called by mutect2, pindel, varscan2
- PRAMEF8 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as rs1469882109; called by muse, mutect2, varscan2
- PREP | c.871G>A p.V291I (on ENST00000369110; = p.V357I on NM_002726.5) | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776771833; called by muse, mutect2, varscan2
- PREP | c.454G>A p.D152N (on ENST00000369110; = p.D218N on NM_002726.5) | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs145682559; called by muse, mutect2, varscan2
- PRF1 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64615188; called by muse, mutect2, varscan2
- PRKAG2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs369471907, COSV55243110; called by muse, mutect2, varscan2
- PROX1 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs1253863076, COSV54778508; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR23C | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101356434, COSV68826891; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSD2 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs549742335, COSV51197107; called by muse, mutect2, varscan2
- PSMC2 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1803992; called by muse, mutect2, varscan2
- PTOV1 | c.1240-5C>T | Splice Region (SNP) | VAF 36/117 reads (31%) | catalogued as rs374488487; called by muse, mutect2, varscan2
- PTPN13 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV57403561; called by muse, mutect2
- PTPN21 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs370512291; called by muse, mutect2, varscan2
- PTPN3 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as rs147740778; called by muse, varscan2
- PTPRN2 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs748139505, COSV67028084; called by muse, mutect2, varscan2
- PTTG1IP | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs147066771, COSV100445971; called by muse, mutect2, varscan2
- PTX3 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs964444797; called by muse, varscan2
- PUF60 | c.1394T>C p.V465A (on ENST00000526683 / NM_001362896.2; = p.V448A on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV57590370; called by muse, mutect2
- PXDN | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV53237482; called by muse, mutect2, varscan2
- PXDN | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376058666, COSV53228140; called by muse, mutect2, varscan2
- PZP | c.1765T>C p.S589P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750687932; called by muse, mutect2, varscan2
- QSOX1 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV62581508; called by muse, mutect2
- RABGGTB | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as rs1254878632; called by muse, mutect2, varscan2
- RALGDS | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as rs774408770, COSV64426191; called by muse, varscan2
- RASSF7 | c.1035-5C>T | Splice Region (SNP) | VAF 52/186 reads (28%) | catalogued as rs200464920, COSV100272711; called by muse, mutect2, varscan2
- RBL2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs748585227; called by muse, mutect2, varscan2
- RBM39 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 131/542 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs747547781, COSV53614918; called by muse, varscan2
- RCAN2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs770255594, COSV100149047, COSV57819878; called by muse, mutect2, varscan2
- REEP1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1351359618, COSV51257608; called by muse, mutect2, varscan2
- REEP4 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs765020107; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | catalogued as rs753959887; called by mutect2, varscan2
- RFX5 | c.56dup p.G20Rfs*4 | Frame Shift Ins (INS) | VAF 41/150 reads (27%) | catalogued as rs758904746; called by mutect2, varscan2
- RHOXF1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs782318799, COSV54294028; called by muse, mutect2, varscan2
- RIMS2 | c.1523G>A p.R508H (on ENST00000666250 / NM_001348490.2; = p.R316H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV51669990; called by muse, mutect2, varscan2
- RIMS2 | c.2443A>T p.I815F (on ENST00000666250 / NM_001348490.2; = p.I623F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51694710; called by muse, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 58/191 reads (30%) | catalogued as rs760343057; called by mutect2, varscan2
- RNASE11 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV60088378; called by muse, mutect2, varscan2
- RNF111 | c.2297+1G>A p.X766_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV62087020; called by muse, mutect2, varscan2
- RNF17 | c.2201T>C p.V734A | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV55043793; called by muse, mutect2
- RNF19A | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV61994610; called by muse, mutect2, varscan2
- RNF213 | c.8227G>A p.A2743T | Missense Mutation (SNP) | VAF 128/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60399387; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 47/72 reads (65%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO4 | c.2561dup p.V855Sfs*28 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | catalogued as rs745506702; called by mutect2, pindel, varscan2
- ROCK1 | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1411987132; called by muse, mutect2, varscan2
- ROR2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.431); catalogued as rs749699077; called by muse, mutect2, varscan2
- RP1L1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373409421; called by muse, mutect2, varscan2
- RP1L1 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66756032; called by muse, mutect2, varscan2
- RPA1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759142510, COSV54608917; called by muse, mutect2, varscan2
- RPH3A | c.736C>T p.R246* (on ENST00000389385 / NM_001143854.2; = p.R242* on NM_014954.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as rs760818180; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1426063032; called by muse, mutect2, varscan2
- RPTOR | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100157385; called by muse, mutect2, varscan2
- RRBP1 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs868021520; called by muse, mutect2
- RRP36 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs552159549; called by muse, mutect2, varscan2
- RRP9 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1289064605; called by muse, mutect2, varscan2
- RTEL1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778675789; called by muse, mutect2, varscan2
- RTL4 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as rs139116920, COSV100465786, COSV61207359; called by muse, mutect2, varscan2
- RTP2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs754331122, COSV64079023; called by muse, mutect2, varscan2
- RUSC2 | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs766414451; called by muse, mutect2, varscan2
- RYR1 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as rs901087791, CM152876, COSV62096697; called by muse, mutect2, varscan2
- RYR1 | c.5480G>A p.R1827H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769949286, COSV62100868; called by muse, mutect2, varscan2
- SAMSN1 | c.880A>G p.R294G | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53468511; called by muse, mutect2, varscan2
- SARDH | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1366811300, COSV53832611, COSV53833571; called by muse, mutect2, varscan2
- SASH3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.375); catalogued as rs766601056, COSV63555743; called by muse, mutect2, varscan2
- SBF1 | c.2005T>G p.C669G | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62369767; called by muse, mutect2, varscan2
- SCARB1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.026); catalogued as rs973192286; called by muse, mutect2, varscan2
- SCN3A | c.3483_3485del p.E1161del | In Frame Del (DEL) | VAF 133/438 reads (30%) | catalogued as rs1553520243; called by pindel, varscan2
2,311 further variants in this file (1,290 protein-altering or splice-affecting, 582 silent, 439 other) are not listed here.
